Somatic mutation profile of tumor specimen MMRF_1716_1_BM_CD138pos (aliquot MMRF_1716_1_BM_CD138pos_T1_KBS5U_L05783) from MMRF case MMRF_1716, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: female; Vital status: Dead; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 84.1 years (30,731 days).
Specimen MMRF_1716_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) edc01de0-14d0-4849-b843-32f2444cc87a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1716_1_PB_WBC (Blood Derived Normal), aliquot MMRF_1716_1_PB_WBC_C3_KBS5U_L05798; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b159f8d2-5acb-45fa-82ad-89afe4442c09

The open-access MAF lists 116 somatic variants for this specimen: 44 protein-altering or splice-affecting, 11 silent, 61 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 37, 3'UTR 36, Intron 11, Silent 11, 3'Flank 5, 5'UTR 4, 5'Flank 3, Nonsense Mutation 3, Frame Shift Del 2, RNA 2, Splice Site 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 17/61 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- ALG13 | c.2395C>A p.R799S | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as COSV52639820; called by muse, mutect2, varscan2
- ANKRD63 | c.961G>A p.G321S | Missense Mutation (SNP) | VAF 23/93 reads (25%) | SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.86); catalogued as rs548350305; called by muse, mutect2, varscan2
- B4GALT5 | c.145C>T p.Q49* | Nonsense Mutation (SNP) | VAF 10/166 reads (6%) | catalogued as rs1464089312; called by muse, mutect2
- BRD3 | c.1086+5G>A | Splice Region (SNP) | VAF 9/22 reads (41%) | catalogued as rs1220860509; called by muse, mutect2, varscan2
- C10orf120 | c.788G>A p.R263H | Missense Mutation (SNP) | VAF 60/149 reads (40%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.653); catalogued as rs779045537; called by muse, mutect2, varscan2
- CHGB | c.463C>T p.R155C | Missense Mutation (SNP) | VAF 35/70 reads (50%) | SIFT tolerated (0.11); PolyPhen benign (0.354); catalogued as rs369985726; called by muse, mutect2, varscan2
- FREM2 | c.9020G>A p.R3007Q | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.984); catalogued as rs759757673, COSV54828636; called by muse, mutect2
- GLT1D1 | c.710C>T p.A237V (on ENST00000442111 / NM_001366889.1; = p.A157V on NM_144669.3) | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.67); catalogued as rs773452218, COSV55886220; called by muse, mutect2, varscan2
- HRH1 | c.790C>T p.P264S | Missense Mutation (SNP) | VAF 42/144 reads (29%) | SIFT tolerated (0.85); PolyPhen benign (0); catalogued as COSV67956062; called by muse, mutect2, varscan2
- IGHV2-70 | c.283T>C p.S95P | Missense Mutation (SNP) | VAF 26/49 reads (53%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs568191048; called by muse, varscan2
- IGKV4-1 | c.182G>C p.W61S | Missense Mutation (SNP) | VAF 33/61 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs778196241; called by muse, mutect2, varscan2
- MMP28 | c.776C>T p.A259V | Missense Mutation (SNP) | VAF 22/69 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.319); catalogued as rs772090801; called by muse, mutect2, varscan2
- NEURL1B | c.407A>G p.N136S | Missense Mutation (SNP) | VAF 40/188 reads (21%) | SIFT tolerated (0.18); PolyPhen benign (0.248); catalogued as rs1474472856; called by muse, mutect2, varscan2
- NTSR2 | c.424C>T p.R142C | Missense Mutation (SNP) | VAF 10/19 reads (53%) | SIFT deleterious (0.03); PolyPhen benign (0.215); catalogued as rs17853770; called by muse, mutect2, varscan2
- PCDHB1 | c.1282G>A p.G428R | Missense Mutation (SNP) | VAF 36/156 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60629993; called by muse, mutect2, varscan2
- POM121C | c.910G>T p.E304* (on ENST00000607367; = p.E62* on NM_001099415.3) | Nonsense Mutation (SNP) | VAF 22/116 reads (19%) | catalogued as COSV99992481; called by muse, mutect2
- PTPRT | c.3978G>C p.Q1326H | Missense Mutation (SNP) | VAF 29/91 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.797); catalogued as COSV61962450; called by muse, mutect2, varscan2
- RELN | c.8050C>T p.R2684C | Missense Mutation (SNP) | VAF 28/100 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.776); catalogued as rs781067207; called by muse, mutect2, varscan2
- RTP1 | c.439G>A p.E147K | Missense Mutation (SNP) | VAF 19/92 reads (21%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.903); catalogued as rs1346870481; called by muse, mutect2, varscan2
- SGF29 | c.833A>G p.N278S | Missense Mutation (SNP) | VAF 89/207 reads (43%) | SIFT tolerated (0.56); PolyPhen benign (0.023); catalogued as rs144681292; called by muse, mutect2, varscan2
- VAV3 | c.1018-1G>C p.X340_splice | Splice Site (SNP) | VAF 16/56 reads (29%) | catalogued as COSV58387829; called by muse, mutect2, varscan2
- VWCE | c.1754C>T p.P585L | Missense Mutation (SNP) | VAF 13/61 reads (21%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as COSV57113671; called by muse, mutect2, varscan2
- ABCA8 | c.2948C>T p.A983V | Missense Mutation (SNP) | VAF 31/130 reads (24%) | SIFT tolerated (0.54); PolyPhen benign (0.045); called by muse, mutect2, varscan2
- CFAP52 | c.773G>A p.C258Y | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT tolerated (0.07); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- CHST8 | c.448C>A p.H150N | Missense Mutation (SNP) | VAF 15/71 reads (21%) | SIFT tolerated (0.41); PolyPhen benign (0); called by muse, mutect2, varscan2
- CREBBP | c.553C>T p.H185Y | Missense Mutation (SNP) | VAF 31/98 reads (32%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.44); called by muse, mutect2, varscan2
- DACH2 | c.4G>A p.A2T | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.223); called by muse, mutect2, varscan2
- FRMD5 | c.400G>A p.A134T | Missense Mutation (SNP) | VAF 24/88 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- LDHB | c.976G>A p.D326N | Missense Mutation (SNP) | VAF 9/19 reads (47%) | SIFT tolerated (0.49); PolyPhen benign (0.003); called by muse, varscan2
- MAP3K15 | c.3329C>T p.P1110L | Missense Mutation (SNP) | VAF 21/49 reads (43%) | SIFT deleterious (0); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- MARCHF3 | c.392A>G p.E131G | Missense Mutation (SNP) | VAF 100/240 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.859); called by muse, mutect2, varscan2
- NR3C1 | c.303C>A p.D101E | Missense Mutation (SNP) | VAF 20/200 reads (10%) | SIFT tolerated, low confidence (0.47); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- PDGFRB | c.1410del p.E471Kfs*10 | Frame Shift Del (DEL) | VAF 29/243 reads (12%) | called by mutect2, pindel, varscan2
- PRPF39 | c.1781A>T p.H594L | Missense Mutation (SNP) | VAF 16/40 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- RB1CC1 | c.2529A>T p.E843D | Missense Mutation (SNP) | VAF 28/67 reads (42%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.277); called by muse, mutect2, varscan2
- REV3L | c.857C>T p.S286L | Missense Mutation (SNP) | VAF 23/86 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- SLC16A10 | c.373A>T p.I125F | Missense Mutation (SNP) | VAF 20/78 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- SLC17A5 | c.51_54del p.D18Afs*24 | Frame Shift Del (DEL) | VAF 22/101 reads (22%) | called by mutect2, pindel, varscan2
- SLC9A6 | c.641A>C p.D214A | Missense Mutation (SNP) | VAF 34/119 reads (29%) | SIFT tolerated (0.09); PolyPhen benign (0.06); called by muse, mutect2, varscan2
- STAT3 | c.1133T>G p.L378R | Missense Mutation (SNP) | VAF 26/107 reads (24%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.787); called by muse, mutect2, varscan2
- SVEP1 | c.833C>A p.S278* | Nonsense Mutation (SNP) | VAF 76/264 reads (29%) | called by muse, varscan2
- TRIM6-TRIM34 | c.2504T>A p.M835K | Missense Mutation (SNP) | VAF 134/550 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- ZSWIM6 | c.18G>C p.Q6H | Missense Mutation (SNP) | VAF 13/53 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); called by muse, mutect2, varscan2
- DUSP2 | c.792T>C p.S264= | Silent (SNP) | VAF 40/121 reads (33%) | catalogued as rs561327206; called by muse, mutect2, varscan2
- ERCC4 | c.2274G>C p.L758= | Silent (SNP) | VAF 10/136 reads (7%) | catalogued as COSV61311964; called by muse, mutect2
- GALT | c.96C>A p.I32= | Silent (SNP) | VAF 20/153 reads (13%) | called by muse, mutect2, varscan2
- KIF3B | c.1365G>T p.R455= | Silent (SNP) | VAF 20/49 reads (41%) | catalogued as COSV65227996; called by muse, mutect2, varscan2
- MBOAT1 | c.1128G>A p.L376= | Silent (SNP) | VAF 16/93 reads (17%) | catalogued as rs767429912, COSV61126709; called by muse, mutect2, varscan2
- OSR1 | c.294C>T p.P98= | Silent (SNP) | VAF 45/142 reads (32%) | called by muse, mutect2, varscan2
- PI4KB | c.2310A>C p.R770= (on ENST00000368873 / NM_001369623.1; = p.R782= on NM_002651.4 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 52/157 reads (33%) | called by muse, mutect2, varscan2
- RLN1 | c.27G>C p.L9= | Silent (SNP) | VAF 26/195 reads (13%) | called by muse, mutect2, varscan2
- SLC43A3 | c.633G>A p.G211= | Silent (SNP) | VAF 101/170 reads (59%) | called by muse, mutect2, varscan2
- SNX1 | c.771G>A p.Q257= | Silent (SNP) | VAF 31/157 reads (20%) | called by muse, mutect2, varscan2
- TULP4 | c.2358C>T p.S786= | Silent (SNP) | VAF 19/105 reads (18%) | catalogued as rs1317532812; called by muse, mutect2, varscan2
- AC093536.1 | n.86G>T | RNA (SNP) | VAF 11/31 reads (35%) | called by muse, varscan2
- ADA | c.*150C>A | 3'UTR (SNP) | VAF 38/109 reads (35%) | called by muse, mutect2, varscan2
- ADGRB2 | c.4572+16C>A | Intron (SNP) | VAF 8/21 reads (38%) | called by muse, mutect2, varscan2
- ARHGAP26 | c.*3578G>C | 3'UTR (SNP) | VAF 10/70 reads (14%) | called by muse, mutect2
- ARID2 | chr12:45727402 C>T | 5'Flank (SNP) | VAF 22/76 reads (29%) | called by muse, mutect2, varscan2
- ATRNL1 | c.*1898A>G | 3'UTR (SNP) | VAF 25/69 reads (36%) | called by muse, mutect2, varscan2
- AVPR2 | chrX:153905039 A>C | 5'Flank (SNP) | VAF 26/51 reads (51%) | called by muse, mutect2, varscan2
- BMP6 | c.*975C>T | 3'UTR (SNP) | VAF 17/72 reads (24%) | called by muse, mutect2, varscan2
- BTG2 | c.*115_*117del | 3'UTR (DEL) | VAF 16/66 reads (24%) | called by pindel, varscan2
- C21orf91 | c.*209T>C | 3'UTR (SNP) | VAF 21/63 reads (33%) | catalogued as rs1034293738; called by muse, mutect2, varscan2
- CA10 | c.-93T>C | 5'UTR (SNP) | VAF 10/37 reads (27%) | called by muse, mutect2, varscan2
- CACNA2D1 | c.*129dup | 3'UTR (INS) | VAF 32/137 reads (23%) | called by mutect2, pindel, varscan2
- CHI3L2 | c.*123C>T | 3'UTR (SNP) | VAF 8/25 reads (32%) | called by muse, mutect2, varscan2
- CHL1 | c.-71G>C | 5'UTR (SNP) | VAF 81/175 reads (46%) | catalogued as COSV99850312; called by muse, mutect2, varscan2
- CHORDC1 | c.563+250G>A | Intron (SNP) | VAF 25/76 reads (33%) | called by muse, mutect2, varscan2
- CSAD | c.1166+89C>G | Intron (SNP) | VAF 16/36 reads (44%) | called by muse, mutect2, varscan2
- CTNNA2 | c.1057-230570C>A | Intron (SNP) | VAF 105/279 reads (38%) | called by muse, mutect2, varscan2
- CYP27A1 | chr2:218782094 C>G | 5'Flank (SNP) | VAF 14/37 reads (38%) | called by muse, mutect2, varscan2
- DPP8 | c.-1056G>A | 5'UTR (SNP) | VAF 20/89 reads (22%) | called by muse, mutect2, varscan2
- F11R | c.*2329G>T | 3'UTR (SNP) | VAF 14/22 reads (64%) | catalogued as rs191751058; called by muse, mutect2
- FCRL5 | c.*2075A>G | 3'UTR (SNP) | VAF 31/103 reads (30%) | called by muse, mutect2, varscan2
- FSD2 | c.*3180_*3191delinsT | 3'UTR (DEL) | VAF 18/63 reads (29%) | called by pindel, varscan2*
- GADL1 | c.1250+1232C>A | Intron (SNP) | VAF 10/35 reads (29%) | catalogued as rs1055442884; called by muse, mutect2, varscan2
- GET4 | c.155+1474T>C | Intron (SNP) | VAF 69/233 reads (30%) | catalogued as rs1270820534; called by muse, mutect2, varscan2
- GPAT4 | c.*413G>A | 3'UTR (SNP) | VAF 3/43 reads (7%) | catalogued as rs1025514443; called by muse, mutect2
- HEPHL1 | c.*888C>T | 3'UTR (SNP) | VAF 16/64 reads (25%) | called by muse, mutect2, varscan2
- HIPK3 | c.*649del | 3'UTR (DEL) | VAF 11/51 reads (22%) | called by mutect2, pindel, varscan2
- IGLL5 | c.-96C>T | 5'UTR (SNP) | VAF 17/55 reads (31%) | catalogued as rs143799402, COSV73250060, COSV73250979; called by muse, mutect2, varscan2
- IKZF3 | c.*6068A>G | 3'UTR (SNP) | VAF 12/86 reads (14%) | called by muse, mutect2, varscan2
- KCTD12 | c.*1404G>A | 3'UTR (SNP) | VAF 4/30 reads (13%) | called by muse, varscan2
- LINC02870 | n.457G>A | RNA (SNP) | VAF 44/122 reads (36%) | catalogued as rs200449977; called by muse, mutect2, varscan2
- LRATD1 | c.*4014G>A | 3'UTR (SNP) | VAF 19/43 reads (44%) | called by muse, mutect2, varscan2
- MLLT3 | c.*2904_*2905del | 3'UTR (DEL) | VAF 56/252 reads (22%) | called by pindel, varscan2
- MMP26 | c.-145+92453A>G | Intron (SNP) | VAF 53/165 reads (32%) | called by muse, mutect2, varscan2
- MXI1 | chr10:110286607 A>T | 3'Flank (SNP) | VAF 31/77 reads (40%) | called by muse, mutect2, varscan2
- MYEF2 | c.*29A>G | 3'UTR (SNP) | VAF 92/333 reads (28%) | called by muse, mutect2, varscan2
- NLK | c.*1396A>G | 3'UTR (SNP) | VAF 4/65 reads (6%) | catalogued as rs926686580; called by muse, mutect2
- NPR3 | c.*1821G>T | 3'UTR (SNP) | VAF 43/86 reads (50%) | called by muse, mutect2, varscan2
- PGBD5 | chr1:230322254 G>A | 3'Flank (SNP) | VAF 23/92 reads (25%) | catalogued as rs974953875; called by muse, mutect2, varscan2
- PGR | c.*2853T>C | 3'UTR (SNP) | VAF 36/136 reads (26%) | called by muse, mutect2, varscan2
- PIWIL4 | c.*422G>T | 3'UTR (SNP) | VAF 17/74 reads (23%) | called by muse, mutect2, varscan2
- PLAG1 | c.*1934C>T | 3'UTR (SNP) | VAF 11/26 reads (42%) | called by muse, mutect2, varscan2
- PNKD | c.236+1369T>C | Intron (SNP) | VAF 17/48 reads (35%) | called by muse, mutect2, varscan2
- PRDM9 | c.*184A>C | 3'UTR (SNP) | VAF 20/108 reads (19%) | called by muse, mutect2, varscan2
- PTPRD | c.*227A>T | 3'UTR (SNP) | VAF 15/94 reads (16%) | called by muse, mutect2, varscan2
- RBSN | c.*604A>T | 3'UTR (SNP) | VAF 22/62 reads (35%) | called by muse, mutect2, varscan2
- S100A7A | chr1:153420703 A>C | 3'Flank (SNP) | VAF 71/238 reads (30%) | called by muse, mutect2, varscan2
- SLC30A6 | c.*2709G>A | 3'UTR (SNP) | VAF 28/97 reads (29%) | called by muse, mutect2, varscan2
- SLITRK2 | chrX:145827878 A>T | 3'Flank (SNP) | VAF 7/149 reads (5%) | called by muse, mutect2
- SMO | c.*729G>A | 3'UTR (SNP) | VAF 29/95 reads (31%) | catalogued as rs1423774378; called by muse, mutect2, varscan2
- SOX6 | c.1435+14T>G | Intron (SNP) | VAF 20/30 reads (67%) | called by muse, varscan2
- STMP1 | c.*646C>A | 3'UTR (SNP) | VAF 31/136 reads (23%) | called by muse, mutect2, varscan2
- STX11 | c.*614A>G | 3'UTR (SNP) | VAF 30/96 reads (31%) | called by muse, mutect2, varscan2
- THAP9 | c.*809del | 3'UTR (DEL) | VAF 31/84 reads (37%) | called by mutect2, pindel, varscan2
- TIMP2 | c.*226T>C | 3'UTR (SNP) | VAF 17/57 reads (30%) | called by muse, mutect2, varscan2
- TM9SF3 | c.*3972A>G | 3'UTR (SNP) | VAF 33/88 reads (38%) | catalogued as rs984479604; called by muse, mutect2, varscan2
- TUSC3 | c.862+2679T>G | Intron (SNP) | VAF 71/182 reads (39%) | catalogued as COSV101141886; called by muse, mutect2, varscan2
- TUT1 | chr11:62574570 C>G | 3'Flank (SNP) | VAF 6/33 reads (18%) | called by muse, mutect2
- UGT8 | c.*1010T>C | 3'UTR (SNP) | VAF 29/69 reads (42%) | called by muse, mutect2, varscan2
- ZC3H12D | c.445+2175G>T | Intron (SNP) | VAF 50/250 reads (20%) | called by muse, mutect2, varscan2
- ZNF20 | c.*311A>C | 3'UTR (SNP) | VAF 22/105 reads (21%) | called by muse, mutect2, varscan2
